Somatic mutation profile of tumor specimen TCGA-DD-AAEE-01A (aliquot TCGA-DD-AAEE-01A-11D-A40R-10) from TCGA case TCGA-DD-AAEE, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G4; Age at diagnosis: 55.8 years (20,396 days).
Specimen TCGA-DD-AAEE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c465b89f-5d19-407d-85d3-24f192731851.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AAEE-10A (Blood Derived Normal), aliquot TCGA-DD-AAEE-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/94824d90-67f4-4272-9b2e-afc6553de2f1

The open-access MAF lists 90 somatic variants for this specimen: 65 protein-altering or splice-affecting, 24 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 24, Frame Shift Del 3, Splice Site 3, Nonsense Mutation 2, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.133T>C p.S45P | Missense Mutation (SNP) | VAF 79/138 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs121913407, COSV62687880, COSV62689248, COSV62696859; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FBXL4 | c.1444C>T p.R482W | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.723); catalogued as rs398123061, CM138678, COSV100014373; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADCY2 | c.1820C>A p.A607D | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100604137; called by muse, mutect2, varscan2
- ADH4 | c.320G>C p.S107T | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as COSV99644407; called by muse, mutect2, varscan2
- ANK3 | c.9091T>C p.Y3031H | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as COSV99782380; called by muse, varscan2
- APOB | c.12072C>A p.F4024L | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51938173, COSV99268092; called by muse, mutect2, varscan2
- CPEB3 | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV99800645; called by muse, mutect2, varscan2
- CRTAM | c.1153C>T p.H385Y | Missense Mutation (SNP) | VAF 60/151 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99912314; called by muse, varscan2
- CTNNAL1 | c.265A>G p.I89V | Missense Mutation (SNP) | VAF 71/161 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs751084523, COSV57705527; called by muse, mutect2, varscan2
- CUX1 | c.2893A>G p.I965V | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.881); catalogued as rs782375328, COSV99473074; called by muse, mutect2, varscan2
- DGAT1 | c.990T>G p.N330K | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100184208; called by muse, mutect2, varscan2
- DOCK1 | c.3728A>G p.H1243R | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1403147569, COSV99732723; called by muse, mutect2, varscan2
- EBF1 | c.1532C>A p.A511D | Missense Mutation (SNP) | VAF 38/193 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.421); catalogued as COSV100566610; called by muse, mutect2, varscan2
- FHDC1 | c.2821C>T p.R941C | Missense Mutation (SNP) | VAF 54/182 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs567145547, COSV52602896, COSV99035930; called by muse, varscan2
- FILIP1 | c.2529G>C p.L843F | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.03); catalogued as COSV99386160; called by muse, mutect2, varscan2
- FMN2 | c.3943T>C p.W1315R | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100147127; called by muse, mutect2, varscan2
- FOSB | c.555+1G>T p.X185_splice | Splice Site (SNP) | VAF 22/66 reads (33%) | catalogued as COSV100798822; called by muse, mutect2, varscan2
- FOXC2 | c.1466G>T p.R489L | Missense Mutation (SNP) | VAF 158/385 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100234153, COSV100234409; called by muse, mutect2, varscan2
- FZD2 | c.1170G>T p.M390I | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as rs767602533, COSV100190805; called by muse, mutect2, varscan2
- FZR1 | c.1450-2A>G p.X484_splice (on ENST00000395095 / NM_001136198.1; = p.X481_splice on NM_016263.4) | Splice Site (SNP) | VAF 19/29 reads (66%) | catalogued as COSV100281527; called by muse, mutect2, varscan2
- GIMAP7 | c.816A>G p.I272M | Missense Mutation (SNP) | VAF 53/133 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.624); catalogued as COSV100543788; called by muse, mutect2, varscan2
- GPSM3 | c.22G>T p.E8* | Nonsense Mutation (SNP) | VAF 22/44 reads (50%) | catalogued as COSV100901040; called by muse, mutect2, varscan2
- GTF3C4 | c.1692G>T p.K564N | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.922); catalogued as COSV100936091; called by muse, mutect2, varscan2
- IRX4 | c.1320C>A p.D440E | Missense Mutation (SNP) | VAF 47/80 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99180750, COSV99181950; called by muse, mutect2, varscan2
- JPH1 | c.1495A>G p.R499G | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as COSV100646783; called by muse, mutect2, varscan2
- KDM3B | c.4599G>T p.R1533S | Missense Mutation (SNP) | VAF 84/123 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100070240; called by muse, mutect2, varscan2
- LATS1 | c.2306A>G p.Y769C | Missense Mutation (SNP) | VAF 59/78 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99486690; called by muse, mutect2, varscan2
- MAPK4 | c.52G>C p.G18R | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.52); catalogued as COSV101245993; called by muse, mutect2, varscan2
- MMP10 | c.1361A>T p.Q454L | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99666790; called by muse, mutect2, varscan2
- MNDA | c.662C>A p.A221E | Missense Mutation (SNP) | VAF 163/386 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100933446, COSV63742115; called by muse, mutect2, varscan2
- MSANTD1 | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs541435320, COSV70873242, COSV70873285; called by muse, mutect2, varscan2
- MTA2 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 61/165 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV99604528; called by muse, mutect2, varscan2
- NR1H4 | c.1450G>A p.D484N (on ENST00000551379 / NM_001206993.2; = p.D470N on NM_005123.4) | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.258); catalogued as rs1198961142, COSV99501203; called by muse, mutect2, varscan2
- OR4D10 | c.472G>A p.V158M | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as rs200781301; called by muse, mutect2, varscan2
- PADI4 | c.795T>G p.I265M | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV100966922; called by muse, mutect2, varscan2
- PCDHGA10 | c.239C>A p.S80Y | Missense Mutation (SNP) | VAF 56/231 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.863); catalogued as COSV99547023; called by muse, mutect2, varscan2
- PCDHGA8 | c.830T>C p.V277A | Missense Mutation (SNP) | VAF 140/355 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.938); catalogued as COSV99547022; called by muse, mutect2, varscan2
- PCNX1 | c.6404A>G p.H2135R | Missense Mutation (SNP) | VAF 47/61 reads (77%) | SIFT tolerated (0.16); PolyPhen benign (0.138); catalogued as COSV99457226; called by muse, mutect2, varscan2
- PCYT1A | c.1049A>G p.N350S | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as rs200512211, COSV99492456; called by muse, mutect2, varscan2
- PIH1D1 | c.343C>G p.Q115E | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.503); catalogued as COSV51807902, COSV99221209; called by muse, mutect2, varscan2
- PLCL2 | c.1960A>T p.S654C (on ENST00000615277 / NM_001144382.2; = p.S528C on NM_015184.5) | Missense Mutation (SNP) | VAF 54/147 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.895); catalogued as COSV101197000; called by muse, mutect2, varscan2
- POTEE | c.2609C>T p.A870V | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV58224548; called by muse, mutect2, varscan2
- PRPH2 | c.186C>A p.N62K | Missense Mutation (SNP) | VAF 45/92 reads (49%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.914); catalogued as rs755239769, COSV100028246; called by muse, mutect2, varscan2
- PYGO1 | c.16T>A p.S6T | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as COSV100114854; called by muse, mutect2, varscan2
- QRICH2 | c.1919C>T p.A640V | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs530614567, COSV99429699; called by muse, varscan2
- RCBTB2 | c.403A>G p.T135A | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT tolerated (0.16); PolyPhen benign (0.055); catalogued as rs1307222049, COSV100749651, COSV60649707; called by muse, mutect2, varscan2
- RXRB | c.785A>G p.Y262C | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1200610906, COSV100807871; called by muse, mutect2, varscan2
- SAMD7 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV100157080; called by muse, mutect2, varscan2
- SASH1 | c.1976A>G p.Y659C | Missense Mutation (SNP) | VAF 33/40 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66558924; called by muse, mutect2, varscan2
- SETX | c.6574C>G p.L2192V | Missense Mutation (SNP) | VAF 54/139 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99810975; called by muse, mutect2, varscan2
- SH3RF2 | c.1592C>T p.P531L | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV100768038; called by muse, mutect2, varscan2
- SLFN11 | c.1867G>T p.E623* | Nonsense Mutation (SNP) | VAF 189/360 reads (53%) | catalogued as COSV100391028, COSV57698076; called by muse, mutect2, varscan2
- SMARCA1 | c.1526G>A p.S509N | Missense Mutation (SNP) | VAF 115/145 reads (79%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV100946719; called by muse, mutect2, varscan2
- TARBP1 | c.3904A>G p.K1302E | Missense Mutation (SNP) | VAF 143/317 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.038); catalogued as COSV99242110; called by muse, mutect2, varscan2
- TDRD5 | c.2333T>C p.M778T | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV99677177; called by muse, mutect2, varscan2
- TGM5 | c.1631G>A p.S544N (on ENST00000220420 / NM_201631.4; = p.S462N on NM_004245.4) | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV99589317; called by muse, mutect2, varscan2
- TM7SF2 | c.161T>A p.L54Q | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as COSV99659851; called by muse, mutect2, varscan2
- TTC26 | c.895+1G>T p.X299_splice | Splice Site (SNP) | VAF 38/90 reads (42%) | catalogued as COSV100571169, COSV58270208; called by muse, mutect2, varscan2
- TUBA3E | c.469C>A p.L157I | Missense Mutation (SNP) | VAF 114/241 reads (47%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.182); catalogued as COSV99919942; called by muse, mutect2
- MUC2 | c.3885A>C p.L1295F | Missense Mutation (SNP) | VAF 14/252 reads (6%) | SIFT tolerated (0.71); PolyPhen benign (0.003); called by muse, mutect2
- NFIX | c.1240del p.Q414Rfs*49 (on ENST00000592199 / NM_001365902.3; = p.Q414Rfs*50 on NM_002501.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 26/58 reads (45%) | called by mutect2, pindel, varscan2
- PRELID1 | c.617_625del p.K206_A208del | In Frame Del (DEL) | VAF 29/132 reads (22%) | called by mutect2, pindel, varscan2
- TCERG1 | c.1762del p.R588Gfs*17 | Frame Shift Del (DEL) | VAF 30/175 reads (17%) | called by mutect2, pindel, varscan2
- TPTE | c.1591T>A p.F531I (on ENST00000618007 / NM_199261.4; = p.F513I on NM_199259.4) | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- ZNF112 | c.746del p.E249Gfs*70 (on ENST00000337401 / NM_001083335.2; = p.E243Gfs*70 on NM_013380.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 37/109 reads (34%) | called by mutect2, pindel, varscan2
- ARMC4 | c.366C>A p.A122= | Silent (SNP) | VAF 34/90 reads (38%) | catalogued as COSV99519053; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1056G>A p.Q352= | Silent (SNP) | VAF 53/116 reads (46%) | catalogued as COSV99959099; called by muse, mutect2, varscan2
- CCNP | c.99C>G p.A33= | Silent (SNP) | VAF 53/143 reads (37%) | catalogued as COSV99695943; called by muse, mutect2, varscan2
- CKB | c.81C>T p.N27= | Silent (SNP) | VAF 29/36 reads (81%) | catalogued as COSV100818962; called by muse, mutect2, varscan2
- CLCN1 | c.597T>A p.R199= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as COSV100578534; called by muse, mutect2, varscan2
- COLEC12 | c.564C>A p.L188= | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as COSV68374359; called by muse, mutect2, varscan2
- CREB5 | c.834G>T p.P278= (on ENST00000357727 / NM_182898.4; = p.P271= on NM_004904.3) | Silent (SNP) | VAF 57/137 reads (42%) | catalogued as COSV100745528; called by muse, mutect2, varscan2
- EXOC3L4 | c.1236G>A p.E412= | Silent (SNP) | VAF 38/55 reads (69%) | catalogued as rs1398353838, COSV101197722; called by muse, mutect2, varscan2
- HOXC4 | c.288G>T p.S96= | Silent (SNP) | VAF 46/93 reads (49%) | catalogued as COSV100324408; called by muse, mutect2, varscan2
- INTS12 | c.846T>A p.V282= | Silent (SNP) | VAF 50/95 reads (53%) | catalogued as COSV100415926; called by muse, mutect2, varscan2
- KRT6A | c.609C>A p.T203= | Silent (SNP) | VAF 54/132 reads (41%) | catalogued as rs1366320372, COSV100417231; called by muse, mutect2, varscan2
- MMP10 | c.276A>C p.G92= | Silent (SNP) | VAF 52/127 reads (41%) | catalogued as COSV99666792; called by muse, mutect2, varscan2
- MUC2 | c.2589C>T p.Y863= | Silent (SNP) | VAF 43/103 reads (42%) | catalogued as rs559546110; called by muse, mutect2, varscan2
- MYH6 | c.1650G>A p.K550= | Silent (SNP) | VAF 49/99 reads (49%) | catalogued as COSV100676997; called by muse, mutect2, varscan2
- OR10C1 | c.795C>T p.A265= (on ENST00000622521; = p.A263= on NM_013941.3) | Silent (SNP) | VAF 28/70 reads (40%) | catalogued as COSV101010893, COSV65822381; called by muse, mutect2, varscan2
- PDHA1 | c.390C>T p.S130= | Silent (SNP) | VAF 83/251 reads (33%) | catalogued as rs756138817, COSV63328050; called by muse, mutect2, varscan2
- SI | c.2322G>A p.R774= | Silent (SNP) | VAF 28/63 reads (44%) | catalogued as COSV52266138; called by muse, mutect2, varscan2
- SLX4 | c.5109G>A p.V1703= | Silent (SNP) | VAF 28/82 reads (34%) | catalogued as rs777602041, COSV99568559; called by muse, mutect2, varscan2
- TECTA | c.4008C>A p.G1336= | Silent (SNP) | VAF 545/1349 reads (40%) | catalogued as COSV50695931, COSV99881568; called by muse, mutect2, varscan2
- TFCP2 | c.57G>A p.V19= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as COSV99227855; called by muse, mutect2, varscan2
- UGP2 | c.342T>C p.N114= | Silent (SNP) | VAF 63/146 reads (43%) | catalogued as COSV100451760; called by muse, mutect2, varscan2
- UNC5CL | c.48G>A p.L16= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as COSV99770983; called by muse, mutect2, varscan2
- ZBTB4 | c.348T>C p.S116= | Silent (SNP) | VAF 3/49 reads (6%) | catalogued as rs1357863923, COSV100263759; called by muse, mutect2
- ZNF101 | c.480A>G p.T160= | Silent (SNP) | VAF 49/104 reads (47%) | catalogued as COSV100543638; called by muse, mutect2, varscan2
- MIR222 | n.75A>G | RNA (SNP) | VAF 25/29 reads (86%) | called by muse, mutect2, varscan2
